Gene-level copy-number profile of tumor specimen TCGA-NC-A5HL-01A from TCGA case TCGA-NC-A5HL, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.9 years (26,977 days).
Specimen TCGA-NC-A5HL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.43098392-27ff-4e69-8d18-6d779c794dc5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a710279-8592-4bd9-b721-1ddf325f50a9

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 243; copy number 1: 31,733; copy number 2: 19,319; copy number 3: 4,862; copy number 4: 2,101; copy number 5: 296; copy number 6: 205; copy number 7: 196; copy number 8: 17; copy number 9: 481; copy number 10: 325; copy number 11: 26; copy number 15: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HL-01A-11D-A26L-01): tumor purity 0.5, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 243 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 8 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:132,783,179–133,761,125, 59 genes: NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, TUBGCP2, AL360181.2, ZNF511, ZNF511-PRAP1, CALY, BANF1P2, AL360181.1, PRAP1, FUOM, ECHS1, MIR3944, AL360181.4, PAOX, AL360181.3, MTG1, SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, AL731769.1, FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15.
- chr14:80,954,989–82,746,664, 26 genes: TSHR, BHLHB9P1, RPL17P3, AC007262.1, AC007262.2, NMNAT1P1, AL136040.2, GTF2A1, SNORA79, AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1, Metazoa_SRP, LINC02301, ENSAP2.
- chr14:91,060,333–91,225,632, 3 genes (within-gene range 0–1): DGLUCY, RNU7-30P, SNORA11B.
- chr14:106,037,902–106,875,071, 130 genes (broad region; genes not listed).
- chr15:66,984,103–67,065,268, 2 genes (within-gene range 0–1): AC087482.1, HMGN2P47.
- chr15:101,751,032–101,933,350, 12 genes (within-gene range 0–1): DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 8,516 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,031,216–121,580,524, 75 genes, copy number 3 (broad region; genes not listed).
- chr3:84,958,989–86,991,149, 12 genes, copy number 3 (within-gene range 1–6): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3.
- chr3:137,880,295–162,601,792, 415 genes, copy number 5–10 (broad region; genes not listed).
- chr3:166,160,021–198,222,513, 628 genes, copy number 7–9 (broad region; genes not listed).
- chr4:46,993,723–55,161,880, 112 genes, copy number 4–6 (within-gene range 1–6) (broad region; genes not listed).
- chr5:4,012,708–4,147,429, 3 genes, copy number 3: AC025773.1, AC025187.1, LINC02063.
- chr5:17,684,584–23,329,892, 40 genes, copy number 3–4: LINC02223, RPL36AP21, SNORD81, RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1.
- chr5:37,106,228–37,249,421, 1 gene, copy number 4 (within-gene range 1–4): CPLANE1.
- chr5:37,209,364–40,755,963, 56 genes, copy number 3–4 (within-gene range 2–4): OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4.
- chr6:41,335,608–58,438,364, 333 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr6:63,521,746–66,728,904, 20 genes, copy number 3: PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr7:33,014,114–33,877,180, 9 genes, copy number 3 (within-gene range 2–3): NT5C3A, RPS29P14, RN7SL505P, RP9, BBS9, AC074338.1, RNA5SP229, AC007312.1, AC006195.1.
- chr7:94,695,027–101,629,296, 224 genes, copy number 4 (broad region; genes not listed).
- chr7:101,822,247–101,961,894, 2 genes, copy number 4: AC005096.1, AC005072.1.
- chr8:13,083,361–13,604,610, 1 gene, copy number 5 (within-gene range 1–5): DLC1.
- chr8:13,338,574–14,023,422, 11 genes, copy number 5: AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1.
- chr8:14,161,084–14,487,879, 5 genes, copy number 5: AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P.
- chr8:33,540,185–34,346,731, 15 genes, copy number 5: RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3.
- chr8:37,559,992–52,022,974, 253 genes, copy number 3–4 (broad region; genes not listed).
- chr8:52,150,820–52,154,892, 1 gene, copy number 3: AC021915.2.
- chr8:128,150,116–128,564,679, 4 genes, copy number 3: MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:135,457,456–135,742,495, 3 genes, copy number 3 (within-gene range 1–3): KHDRBS3, MAPRE1P1, RNU1-35P.
- chr8:135,977,329–135,980,588, 1 gene, copy number 3: AC103955.1.
- chr9:14,475–21,699,596, 308 genes, copy number 4 (broad region; genes not listed).
- chr9:21,994,139–22,128,103, 1 gene, copy number 4 (within-gene range 0–4): CDKN2B-AS1.
- chr9:22,046,758–43,045,120, 456 genes, copy number 4 (broad region; genes not listed).
- chr11:56,699,095–65,326,543, 446 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr11:95,482,406–95,497,553, 1 gene, copy number 4: AP001790.1.
- chr15:92,762,757–93,027,996, 9 genes, copy number 4: AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175.
- chr17:26,981,694–83,095,122, 2,120 genes, copy number 3 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 3–4 (broad region; genes not listed).
- chr19:11,639,754–41,074,107, 1,184 genes, copy number 3–15 (broad region; genes not listed).
- chr20:30,278,906–35,742,312, 191 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr21:10,328,411–36,079,389, 422 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr22:20,241,415–38,656,629, 778 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29,312. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
